Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7QK, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7QK-01C (Primary Tumor).

[page 1 of 11]
Gender: Male	Birth Date	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology [OrderID:	Final Results
------------------------------	---------------

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS:

1. Kidney, left, tumor #1, partial nephrectomy: Renal cell carcinoma, chromophobe type.
2. Kidney, left, tumor #2, partial nephrectomy: Renal cell carcinoma, chromophobe type.
3. Kidney, left, tumor #3, partial nephrectomy: Hybrid tumor with areas of chromophobe and oncocytoma present.
4. Kidney, left, tumor #4, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
5. Kidney, left, tumor #5, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
6. Kidney, left, tumor #6, partial nephrectomy: Hybrid tumor, predominantly chromophobe type.
7. Kidney, left, tumor #7, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
8. Kidney, left, tumor #8, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
9. Kidney, left, tumor #9, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
10. Kidney, left, tumor #10, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
11. Kidney, left, tumor #11, partial nephrectomy: Hybrid tumor with oncocytosis.
12. Kidney, left, tumor #12, partial nephrectomy: Hybrid tumor.
13. Kidney, left, tumor #13, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
14. Kidney, left, tumor #14, partial nephrectomy: Hybrid tumor.
15. Kidney, left, tumor #15, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
16. Kidney, left, tumor #16, partial nephrectomy: Hybrid tumor.
17. Kidney, left, tumor #17, partial nephrectomy: Hybrid tumor.
18. Kidney, left, tumor #18, partial nephrectomy: Hybrid tumor with oncocytosis.

ICD-O-3
Carcinoma, renal cell chromophobe type
Site @ Kidney NOS
C64.9
JW 9/24/13
8317/3

[page 2 of 11]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:
Surgical Pathology (OrderID:			Final Results

19. Kidney, left, tumor #19, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
20. Kidney, left, tumor #20, partial nephrectomy: Hybrid tumor with oncocytosis.
21. Kidney, left, tumor #21, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
22. Kidney, left, tumor #22, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
23. Kidney, left, tumor #23, partial nephrectomy: Hybrid tumor.
24. Kidney, left, tumor #24, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
25. Kidney, left, tumor #25, partial nephrectomy: Hybrid tumor.
26. Kidney, left, tumor #26, partial nephrectomy: Hybrid tumor, predominantly chromophobe type.
27. Kidney, left, tumor #27, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
28. Kidney, left, tumor #28, partial nephrectomy: Hybrid tumor.
29. Kidney, left, tumor #29, partial nephrectomy: Hybrid tumor.
30. Kidney, left, tumor #30, partial nephrectomy: Hybrid tumor.
31. Kidney, left, tumor #31, partial nephrectomy: Hybrid tumor.
32. Kidney, left, tumor #32, partial nephrectomy: Hybrid tumor.
33. Kidney, left, tumor #33, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
34. Kidney, left, tumor #34, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
35. Kidney, left, tumor #35, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.
36. Kidney, left, tumor #36, partial nephrectomy: Hybrid tumor.
37. Kidney, left, tumor #37, partial nephrectomy: Hybrid tumor.
38. Kidney, left, tumor #38, partial nephrectomy: Hybrid tumor.
39. Kidney, left, tumor #39, partial nephrectomy: Hybrid tumor, predominantly oncocytoma type.

[page 3 of 11]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology (OrderID:**Final Results**

40. Kidney, left, tumor #40, partial nephrectomy: Hybrid tumor.

41. Kidney, left, tumor #41, partial nephrectomy: Hybrid tumor.

42. Kidney, left, "normal", partial nephrectomy: Hybrid tumor.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: male with Birt Hogg Dube syndrome, bilateral multifocal renal tumors.

Specimen Taken For Protocol:

Allocate Order to Protocol:

PROCEDURE: Pre-Operative Diagnosis: Birt Hogg Dube.

Post-Operative Diagnosis: same.

Operative Findings: 41 tumors.

SPECIMENS SUBMITTED: 1. KIDNEY, LEFT, Tumor #1

2. KIDNEY, LEFT, Tumor #2
3. KIDNEY, LEFT, Tumor #3
4. KIDNEY, LEFT, Tumor #4
5. KIDNEY, LEFT, Tumor #5
6. KIDNEY, LEFT, Tumor #6
7. KIDNEY, LEFT, Tumor #7
8. KIDNEY, LEFT, Tumor #8
9. KIDNEY, LEFT, Tumor #9
10. KIDNEY, LEFT, Tumor #10
11. KIDNEY, LEFT, Tumor #11
12. KIDNEY, LEFT, Tumor #12
13. KIDNEY, LEFT, Tumor #13
14. KIDNEY, LEFT, Tumor #14
15. KIDNEY, LEFT, Tumor #15
16. KIDNEY, LEFT, Tumor #16
17. KIDNEY, LEFT, Tumor #17
18. KIDNEY, LEFT, Tumor #18
19. KIDNEY, LEFT, Tumor #19
20. KIDNEY, LEFT, Tumor #20
21. KIDNEY, LEFT, Tumor #21
22. KIDNEY, LEFT, Tumor #22
23. KIDNEY, LEFT, Tumor #23
24. KIDNEY, LEFT, Tumor #24
25. KIDNEY, LEFT, Tumor #25
26. KIDNEY, LEFT, Tumor #26

[page 4 of 11]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology [OrderID:**Final Results**

27. KIDNEY, LEFT, Tumor #27
28. KIDNEY, LEFT, Tumor #28
29. KIDNEY, LEFT, Tumor #29
30. KIDNEY, LEFT, Tumor #30
31. KIDNEY, LEFT, Tumor #31
32. KIDNEY, LEFT, Tumor #32
33. KIDNEY, LEFT, Tumor #33
34. KIDNEY, LEFT, Tumor #34
35. KIDNEY, LEFT, Tumor #35
36. KIDNEY, LEFT, Tumor #36
37. KIDNEY, LEFT, Tumor #37
38. KIDNEY, LEFT, Tumor #38
39. KIDNEY, LEFT, Tumor #39
40. KIDNEY, LEFT, Tumor #40
41. KIDNEY, LEFT, Tumor #41
42. KIDNEY, LEFT, Normal left kidney

GROSS DESCRIPTION: Received are 42 freshly submitted specimens, each in containers labeled with the patient's name, medical record number, and further specified as follows:

1. "Left kidney tumor #1" is an ovoid tan-pink nodule measuring 5.1 x 5 x 4.5 cm with a portion of overlying kidney capsule and fat covering approximately one-third of the surface. While in vivo, two tissue needle core biopsies were procured for by in the . The nodules are bisected revealing a mottled orange-yellow, soft, rubbery cut surface with an eccentrically positioned white-tan focus, 1.5 x 1 cm. Approximately 50% of tissue is procured for . Gross photographs are taken. The remainder of the specimen is placed into and submitted to Pathology for permanent processing. Per margin assessment is not necessary on any of the 42 specimens submitted today. The specimen is received in Surgical Pathology matching the above description. The remainder of the nodules is further sectioned and represented in white cassettes #1A-1J.

2. "Left kidney tumor #2" is a slighted disrupted multiple lobulated binodular mass, 4.8 x 4 x 3.3 cm with a portion of overlying kidney capsule covering approximately one-third of the specimen. In the procured 2 in vivo tissue needle core biopsies from this tumor which he designated as lower pole 4-cm tumor, entirely procured for . The nodule is bisected revealing a mottled orange-yellow soft, rubbery cut surface with an eccentrically positioned white-tan focus in each of the nodularities. Approximately 50% of tissue is procured for from the nodule. Gross photographs are taken. The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the nodule is serially sectioned and represented in white cassettes #2A-2H.

3. "Left kidney tumor #3" is a multilobulated tan-pink nodule designated as "upper pole lateral" by .

[page 5 of 11]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology [OrderID:**Final Results**

measuring 4 x 3.8 x 3.5 cm. In the procured in
2 tumor tissue needle core biopsies for The nodule is
bisected revealing a slightly mottled orange-yellow soft, rubbery
cut surface with a central white-tan focus. Approximately 50% of
the nodule is procured for Gross photographs are taken. The
remainder of the specimen is placed into and submitted to
Pathology for permanent processing. In Surgical Pathology, the
specimen matches the above description. The remainder of the
nodule is serially sectioned and represented in white cassettes
#3A-3H.

4. "Left kidney tumor #4" is a multilobulated tan-pink nodule
designated in the as "upper pole medial" by
measuring 3.8 x 3 x 2.1 cm which is one-fourth covered by kidney
capsule and perirenal fat. In the procured 2 in
tissue needle core biopsies from the tumor for The
nodule is sectioned revealing a similar cut surface as the
previous 3 nodules. Approximately 50% of tissue from the nodule
is procured for Gross photographs are taken. The remainder
of the specimen is placed into and submitted to Pathology
for permanent processing. In Surgical Pathology, the specimen
matches the above description. The remainder of the nodule is
sectioned and represented in white cassettes #4A-4H.

5. "Left kidney tumor #5" is an irregularly-shaped brown-orange
nodular tissue fragment measuring 4.5 x 2.8 x 2.8 cm which is half
covered by the kidney capsule and fat. It is bisected revealing a
similar cut surface as the previously described nodules.
Approximately 50% of tissue is procured for Gross
photographs are taken. The remainder of the specimen is submitted
to Pathology for permanent processing. In Surgical Pathology, the
specimen matches the above description. The remainder of the
nodule is sectioned and represented in white cassettes
#5A-5G.

6. "Left kidney tumor #6" is a previously disrupted maroon-red
tissue fragment, overall 1.8 x 1.1 x 1 cm. No tissues are
procured. The specimen is submitted to Pathology in its entirety
for permanent processing. In Surgical Pathology, the specimen
matches the above description. The tissue is serially sectioned
and entirely submitted in white cassettes 6A-6C.

7. "Left kidney tumor #7" is an irregularly-shaped yellow-orange
nodular tissue fragment, 1.4 x 1.3 x 1.1 cm. No tissues are
procured. The specimen is entirely submitted to Pathology for
permanent processing. In Surgical Pathology, the specimen matches
the above description. The fragment is serially sectioned and
entirely submitted in white cassettes B.

8. "Left kidney tumor #8" is an irregularly-shaped tan-brown nodular
tissue fragment, 2.1 x 1.6 x 1.4 cm. It is bisected revealing a
similar cut surface with the white foci as previously described in
the other nodules. Gross photographs are taken. Approximately
40% of nodular tissue is procured for The remainder of the

[page 6 of 11]
		Admit Protocol:
Gender: Male	Birth Date:	Age:
Admit Protocol:	Admit Protocol:	Location:

Surgical Pathology [OrderID:	Final Results
------------------------------	---------------

specimen is placed into formalin and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the nodule is sectioned and represented in white cassettes 8A-8C.

9. "Left kidney tumor #9" is an irregularly-shaped brown-orange nodular tissue fragment, 2.4 x 2.0 x 1.7 cm. It is bisected revealing a similarly described cut surface. Approximately 40% of tissue is procured for Gross photographs are taken. The remainder of the specimen is submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is entirely submitted in white cassettes 9C.

10. "Left kidney tumor #10" is an irregularly-shaped brown-orange nodular tissue fragment, 2 x 2 x 1.8 cm. It is bisected revealing a similarly described cut surface. No tissues are procured for Gross photographs are taken. The remainder of the specimen is submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The specimen is serially sectioned and entirely submitted in white cassettes A-10D.

11. "Left kidney tumor #11" is an irregularly-shaped brown-orange nodular tissue fragment, 3 x 2.4 x 1.8 cm with approximately one-fourth covered by renal capsule and attached fat. It is bisected revealing a similarly described cut surface. Gross photographs are taken. Approximately 40% of tissue is procured for The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is sectioned and represented in white cassettes. A-11D.

12. "Left kidney tumor #12" is an irregularly-shaped orange-tan nodular tissue fragment, 2.5 x 2.3 x 2 cm. It is bisected revealing a similarly described cut surface. Approximately 50% of the tissue is procured for The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is serially sectioned and represented in white cassettes #12A-12C.

13. "Left kidney tumor #13" is an irregularly-shaped tan-orange nodular tissue fragment, 2.9 x 2.4 x 1.3 cm which is partially covered by kidney capsule. It is bisected revealing a similarly described cut surface. Approximately 50% is procured for The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is serially sectioned and represented in white cassettes .13A-13D.

14. "Left kidney tumor #14" is an irregular tan-orange nodular

[page 7 of 11]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology (OrderID:	Final Results
------------------------------	---------------

tissue fragment, 1.6 x 1.4 x 1 cm. Approximately 50% of tissue is procured for . The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is entirely submitted in white cassette #14A.

15. "Left kidney tumor #15" is an irregular tan-orange nodular tissue fragment, 1.4 x 1.2 x 1 cm. Approximately 50% of tissue is procured for . The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is serially sectioned and entirely submitted in white cassette #15A.

16. "Left kidney tumor #16" is an irregularly-shaped tan-orange nodular tissue fragment, 3.2 x 2.0 x 1.9 cm, which is one-fourth covered by renal capsule and fat. It is bisected revealing a similarly-described cut surface. Approximately 50% of tissue is procured for . The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology, the remainder of the nodule is sectioned and represented in white cassettes #16A-B.

17. "Left kidney tumor #17" is an irregularly-shaped tan-orange nodular tissue fragment, 2 x 1.8 x 1.8 cm. Approximately 50% of tissue is procured for . The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is serially sectioned and entirely submitted in white cassette #17A-17C.

18. "Left kidney tumor #18" is an irregularly-shaped tan-orange nodular tissue fragment, 1.3 x 1 x 0.7 cm. Approximately 50% of tissue is procured for . The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is sectioned and entirely submitted in white cassette #18A.

19. "Left kidney tumor #19" is an irregularly-shaped tan-orange nodular tissue fragment, 2 x 1.4 x 1.4 cm. Approximately 50% of tissue is procured for . The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is sectioned and entirely submitted in white cassettes A-19C.

20. "Left kidney tumor #20" are 3 tan-orange nodular tissue fragments ranging from 0.8 to 2.1 cm in greatest dimensions and in the aggregate 2.1 x 1.7 x 1 cm. No tissues are procured. The entire specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The specimen is serially

[page 8 of 11]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology [OrderID:**Final Results**

sectioned and entirely submitted in white cassettes
20A-20D.

21. "Left kidney tumor #21" is a single irregularly-shaped orange-tan nodular tissue fragment, 0.6 x 0.5 x 0.4 cm. No tissues are procured. The specimen is entirely submitted in formalin for Pathology. In Surgical Pathology the specimen matches the above description. It is trisected and entirely submitted in white cassette 21A.
22. "Left kidney tumor #22" are 2 orange-tan nodular tissue fragments, in the aggregate 0.7 x 0.6 x 0.5 cm. No tissues are procured. The specimen is entirely placed into formalin and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. It is trisected and entirely submitted in white cassette #22A.
23. "Left kidney tumor #23" is a disrupted tan-orange nodular fragment, 1.4 x 1 x 1 cm. No tissues are procured. The specimen is entirely submitted in for permanent processing. In Surgical Pathology the specimen matches the above description. The specimen is sectioned and entirely submitted in white cassettes 23A-23B.
24. "Left kidney tumor #24" is an irregularly-shaped orange-tan nodular tissue fragment, 1.2 x 1 x 1 cm. Approximately 50% of tissue is procured for The remaining of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. It is further bisected and entirely submitted in white cassette #24.
25. "Left kidney tumor #25" is an irregularly-shaped orange-tan nodular tissue fragment, 1 x 0.6 x 0.5 cm. No tissue is procured. The entire specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. It is bisected and entirely submitted in white cassette #25A.
26. "Left kidney tumor #26" is an irregularly-shaped orange-tan nodular tissue fragment, 1.2 x 1 x 0.9 cm. Approximately 50% of tissue is procured for The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. It is bisected and entirely submitted in white cassette #26A.
27. "Left kidney tumor #27" is an irregularly-shaped orange-tan nodular tissue fragment, 1.6 x 1.4 x 1.3 cm. Approximately 50% of tissue is procured for The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. It is further sectioned and entirely submitted in white cassettes 7A-27B.

[page 9 of 11]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology (OrderID:	Final Results
------------------------------	---------------

28. "Left kidney tumor #28" are four tan-orange nodular tissue fragments ranging from 0.5 to 1.2 cm in greatest dimensions and in the aggregate 1.2 x 1.2 x 1 cm. No tissues are procured. The entire specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. It is entirely submitted in white cassettes #28A-B.

29. "Left kidney tumor #29" is a tan-orange nodular tissue fragment, 2.5 x 1.8 x 1.1 cm which is one-fourths covered by kidney capsule. Approximately 50% of tissue is procured for The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. The remainder of the specimen sectioned and entirely submitted in white cassettes #29A-B.

30. "Left kidney tumor #30" are three tan-orange nodular tissue fragments ranging from 1.0 to 1.4 cm in greatest dimensions and in the aggregate 1.4 x 1.4 x 1 cm. No tissues are procured. The entire specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. The specimen is sectioned and entirely submitted in white cassettes #30A-30B.

31. "L kidney tumor #31" is an irregularly-shaped tan-orange nodular tissue fragment. 1.4 x 0.8 x 0.7 cm. Approximately 50% of tissue is procured for The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. It is further bisected and entirely submitted in white cassette #31A.

32. "L kidney tumor #32" is an irregularly-shaped tan-orange nodular tissue fragment, 1 x 0.8 x 0.6 cm. Approximately 50% of tissue is procured for The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. It is further bisected and entirely submitted in white cassette #32A.

33. "L kidney tumor #33" is an irregularly-shaped tan-orange nodular tissue fragment, 1.3 x 1.1 x 1 cm. Approximately 50% of tissue is procured for The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. The remainder is sectioned and entirely submitted in white cassette #33A.

34. "L kidney tumor #34" are irregularly-shaped tan-orange nodular tissue fragments ranging from 1.3 to 1.8 cm in greatest dimensions and in the aggregate 1.8 x 1.7 x 0.6 cm. No tissues are procured. The entire specimen is placed into and submitted to

[page 10 of 11]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology [OrderID:	Final Results
------------------------------	---------------

Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. The specimen sectioned where needed and entirely submitted in white cassettes #34A-34B.

35. "L kidney tumor #35" is an irregularly-shaped tan-orange nodular tissue fragment, 1.8 x 1.4 x 1.1 cm. Approximately 50% of tissue is procured for The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the remainder of the specimen is further trisected and entirely submitted in white cassettes #35A-35B.

36. "L kidney tumor #36" is a focally disrupted irregularly-shaped tan-orange hemorrhagic nodular tissue fragment, 1.1 x 1 x 0.9 cm. No tissues are procured. The entire specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. It is bisected and entirely submitted in white cassette #36A.

37. "L kidney tumor #37" is an irregularly-shaped tan-orange nodular tissue fragment, 1.5 x 1.2 x 0.7 cm. Approximately 50% of tissue is procured for The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. It is further bisected and entirely submitted in white cassette #37A.

38. "L kidney tumor #38" is an irregularly-shaped tan-orange nodular tissue fragment, 1.5 x 1 x 0.8 cm. Approximately 50% of tissue is procured for The remainder of the specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. It is further bisected and entirely submitted in white cassette #38A.

39. "L kidney tumor #39" is a dome-shaped tan-orange nodular tissue fragment, 0.9 x 0.7 x 0.7 cm. No tissues are procured. The entire specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. It is trisected and entirely submitted in white cassette #39A.

40. "L kidney tumor #40" is an irregularly-shaped tan-orange nodular tissue fragment, 0.6 x 0.5 x 0.4 cm. No tissues are procured. The entire specimen is placed into and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. It is sectioned and entirely submitted in white cassette #40.

41. "L kidney tumor #41" are 2 tan-orange irregularly-shaped nodular tissue fragment with focal hemorrhage, 0.7 and 1.6 cm in greatest dimensions each. No tissues are procured. The entire specimen is

[page 11 of 11]
Gender: Male	Birth Date	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age
		Location:

Surgical Pathology [OrderID:	Final Results
------------------------------	---------------

placed into _____ and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. The larger fragment is sectioned and entirely submitted in white cassette #41A. The smaller is entirely submitted in 41B.

42. "Normal left kidney" is an irregularly-shaped tan-orange-pink nodular tissue fragment, 1.8 x 1.6 x 0.7 cm. In the _____ procured 2 in vivo tissue needle core biopsies for _____ The nodule tissue fragment is sectioned with approximately 50% of _____ Gross photographs are taken. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. In Surgical Pathology the specimen matches the above description. The remainder of the specimen is sectioned and entirely submitted in white cassettes _____ 42A-B.

The procurement was performed by _____

Gross Description dictated by _____

Accessioned: _____

Final Report Signed Out: _____

<Resident Signature> _____

<Sign Out Dr. Signature> _____

Date Report Signed: _____

HI/AA Discrepancy		

Source: NCI Genomic Data Commons file 2b835856-43bd-41e0-932b-1a23a7069995 (TCGA-KM-A7QK.192A2806-61A7-49C9-91D6-B345DDFB7331.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).